Surgical pathology report (de-identified scan), TCGA case TCGA-P4-A5EB, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-A5EB-01A (Primary Tumor).

Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (5 CM IN GREATEST DIMENSION), PAPILLARY TYPE 2, FUHRMAN NUCLEAR GRADE 3, CONFINED TO THE KIDNEY.

Simple renal cyst (3.0 cm) in the upper pole.

Cystic calyceal dilation in the mid portion of kidney.

Margins of resection (ureter, renal artery and renal vein), negative for carcinoma.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A radical nephrectomy specimen 18.0 x 13.0 x 11.0 cm including the right kidney (13.0 x 7.0 x 4.2 cm). A segment of renal artery, renal vein and ureter (12.5 cm in length x 0.7 average diameter).

There is a 5.0 x 4.2 x 4.0 cm well circumscribed tumor mass in the lower pole of kidney. The tumor is tan-white with focal areas of hemorrhage and tan-yellow discoloration. Two cysts are present, one in the mid kidney (3.8 x 3.0 x 3.0 cm) with rough lining, the other in the upper pole (3.0 x 2.5 x 2.5 cm) with smooth lining.

The solid tumor does not invade into the perinephric adipose tissue, renal sinus, or the renal vein. The tumor does not extend into Gerota's fascia. The uninvolved renal parenchyma is grossly unremarkable.

SECTION CODE: A1, margins (ureter, renal vein and artery); A2-A7, tumor and adjacent renal parenchyma; A8, A9, mid pole cyst; A10, A11, superior pole cyst and normal; A12, uninvolved renal parenchyma.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-Y7343

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

—END OF REPORT—

ICD-O-3

Carcinoma, papillary renal cell 8260/3
Site: @ Kidney, NOS C64.9
gid 11/10/13

Reviewed Initials		

Source: NCI Genomic Data Commons file dd9458fa-a40f-455e-901b-c6744ee4611d (TCGA-P4-A5EB.7C921918-BBC3-490D-9D7C-3D250564D395.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).